Somatic mutation profile of tumor specimen C3L-05644-04 (aliquot CPT0346460006) from CPTAC case C3L-05644, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 70.5 years (25,741 days).
Specimen C3L-05644-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e457466-b1e3-435d-a724-72277db960c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05644-31 (Blood Derived Normal), aliquot CPT0346530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69dadbaa-3cbf-4749-b9b5-d5c9d278e574

The open-access MAF lists 739 somatic variants for this specimen: 490 protein-altering or splice-affecting, 226 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 452, Silent 226, Nonsense Mutation 24, Intron 19, Splice Site 5, Splice Region 5, Frame Shift Del 3, 5'UTR 2, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/434 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 126/585 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2
- AC004593.2 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 306/651 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56101583; called by muse, mutect2, varscan2
- ADAMTS16 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 136/453 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1431159881, COSV57010074; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADGRG4 | c.1799C>A p.S600Y | Missense Mutation (SNP) | VAF 217/385 reads (56%) | SIFT tolerated (0.84); PolyPhen benign (0.039); catalogued as COSV54950436; called by muse, mutect2, varscan2
- AFM | c.739T>A p.F247I | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56920740; called by muse, mutect2, varscan2
- AK9 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV58142129; called by muse, mutect2, varscan2
- AKAP6 | c.3743C>T p.S1248F | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV55215144; called by muse, mutect2, varscan2
- ALPK2 | c.3154C>T p.P1052S | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as COSV64495438; called by muse, mutect2, varscan2
- ANO4 | c.929C>T p.T310I (on ENST00000392977 / NM_001286615.2; = p.T275I on NM_178826.4) | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as COSV54597158; called by muse, mutect2, varscan2
- ARHGAP28 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 171/361 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99151420; called by muse, mutect2, varscan2
- ARHGEF5 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 121/552 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412421161; called by muse, varscan2
- ARID2 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100536027; called by muse, mutect2, varscan2
- ARID4B | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 234/485 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51608359; called by muse, mutect2, varscan2
- ASB5 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 163/359 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as COSV56668570; called by muse, mutect2, varscan2
- ASTN1 | c.3487C>T p.L1163F | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62494524, COSV62496511; called by muse, mutect2, varscan2
- ATP9A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 262/597 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756587295, COSV58762895, COSV58762969; called by muse, mutect2, varscan2
- BAAT | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 206/367 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773128969, COSV52287359; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 230/556 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs552665606; called by muse, mutect2
- BRDT | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV62867987; called by muse, mutect2, varscan2
- C12orf40 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100210912; called by muse, mutect2, varscan2
- C14orf93 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 93/434 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as rs753957455; called by muse, mutect2, varscan2
- C1orf141 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV63993407; called by muse, mutect2, varscan2
- C20orf202 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 158/506 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.646); catalogued as rs957069521; called by muse, varscan2
- C2CD2 | c.1514A>G p.K505R | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs374327676; called by muse, mutect2, varscan2
- CCDC197 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs571360105; called by muse, mutect2, varscan2
- CCDC54 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV53758302; called by muse, varscan2
- CDK5RAP1 | c.1141C>T p.P381S (on ENST00000357886 / NM_001365728.1; = p.P367S on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs1476324047; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2, varscan2
- CFHR4 | c.1307C>T p.S436F (on ENST00000367416 / NM_001201551.2; = p.S190F on NM_006684.5) | Missense Mutation (SNP) | VAF 166/393 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52235177, COSV99260064; called by muse, mutect2, varscan2
- COL11A1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 126/293 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62196469; called by muse, mutect2, varscan2
- COL18A1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 219/494 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.029); catalogued as COSV62706917; called by muse, mutect2, varscan2
- COL7A1 | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893823048; called by muse, mutect2, varscan2
- COLGALT2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 214/447 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV62298940; called by muse, mutect2, varscan2
- CR1 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 325/822 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.255); catalogued as rs765221100, COSV65456111; called by muse, mutect2, varscan2
- CSMD3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 115/368 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52332654; called by muse, mutect2, varscan2
- CYFIP2 | c.3644G>A p.G1215E (on ENST00000616178 / NM_001291722.2; = p.G1190E on NM_014376.4) | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV59037753; called by muse, mutect2, varscan2
- CYP2J2 | c.50A>G p.H17R | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs764068656; called by muse, mutect2, varscan2
- DCHS1 | c.6142C>T p.R2048C | Missense Mutation (SNP) | VAF 293/459 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV55034535; called by muse, mutect2, varscan2
- DDX60L | c.4148C>T p.S1383F | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV99487555; called by muse, mutect2, varscan2
- DNAH2 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 130/388 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1368995075, COSV66719944; called by muse, mutect2, varscan2
- DNAH3 | c.8633C>T p.S2878L | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528337515; called by muse, mutect2, varscan2
- DNAH3 | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 142/302 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99770280; called by muse, mutect2, varscan2
- DNAH5 | c.12415C>T p.P4139S | Missense Mutation (SNP) | VAF 209/421 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV54209617; called by muse, mutect2, varscan2
- DNAH5 | c.6106C>T p.R2036C | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768503312, COSV54220109; called by muse, mutect2, varscan2
- DPYD | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs267598786, COSV64609998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSC3 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64571535; called by muse, mutect2, varscan2
- DYNC2H1 | c.7894G>A p.E2632K | Missense Mutation (SNP) | VAF 155/242 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62090043; called by muse, mutect2, varscan2
- ELAVL4 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63914355, COSV63919081; called by muse, mutect2, varscan2
- EOMES | c.1538A>G p.N513S | Missense Mutation (SNP) | VAF 210/452 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.021); catalogued as rs752788023, COSV55416050; called by muse, mutect2, varscan2
- ERCC6L | c.2773C>T p.H925Y | Missense Mutation (SNP) | VAF 181/347 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as rs1258157181; called by muse, mutect2, varscan2
- ESR1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778449608, COSV52781800, COSV52804387; called by muse, mutect2, varscan2
- EXD1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs762464159, COSV59255452; called by muse, mutect2, varscan2
- F5 | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889186; called by muse, mutect2
- FAM81B | c.813A>T p.E271D | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV51984278; called by muse, mutect2, varscan2
- FAM83B | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 135/429 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs867463762, COSV60919997; called by muse, mutect2, varscan2
- FANCD2 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 63/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773734434, COSV99810587; called by muse, mutect2, varscan2
- FCAMR | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 158/622 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs947694511; called by muse, mutect2, varscan2
- FGD6 | c.18G>A p.E6= | Splice Region (SNP) | VAF 67/201 reads (33%) | catalogued as rs750051583, COSV100676734; called by muse, mutect2, varscan2
- FLG | c.5744G>A p.G1915E | Missense Mutation (SNP) | VAF 199/701 reads (28%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as rs145528116, COSV64239448; called by muse, mutect2, varscan2
- FLG | c.5360G>A p.G1787E | Missense Mutation (SNP) | VAF 222/732 reads (30%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.946); catalogued as rs762983931, CD072423; called by muse, mutect2, varscan2
- FMN2 | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 228/513 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1227000930, COSV60447115; called by muse, mutect2, varscan2
- FRMPD2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 166/315 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.141); catalogued as rs760118282; called by muse, mutect2, varscan2
- GABRG1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 164/387 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54962532; called by muse, mutect2, varscan2
- GCN1 | c.5910A>T p.E1970D | Missense Mutation (SNP) | VAF 165/398 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1339235524; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 181/441 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GFRA4 | c.719G>A p.R240H (on ENST00000319242 / NM_145762.3; = p.R210H on NM_022139.4) | Missense Mutation (SNP) | VAF 143/333 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1368782906; called by muse, mutect2, varscan2
- GIMAP1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 443/973 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs766760280, COSV56187351; called by muse, mutect2, varscan2
- GLRB | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52415538; called by muse, mutect2, varscan2
- GNAT2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV63554755; called by muse, mutect2, varscan2
- GP5 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 130/339 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV59878736; called by muse, mutect2, varscan2
- GPR135 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 229/559 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.446); catalogued as rs1281449877; called by muse, mutect2, varscan2
- GPRC5A | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1307353902; called by muse, mutect2, varscan2
- GRIN2A | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58042807; called by muse, mutect2, varscan2
- GRM8 | c.1891C>T p.L631F | Missense Mutation (SNP) | VAF 320/742 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100287240, COSV58808243; called by muse, mutect2, varscan2
- HCN1 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV57522708, COSV57536689; called by muse, mutect2, varscan2
- HDAC9 | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 178/386 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV67776342; called by muse, mutect2, varscan2
- HRNR | c.6925T>A p.S2309T | Missense Mutation (SNP) | VAF 194/3074 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.176); catalogued as rs768424858; called by muse, mutect2
- HTR2C | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 241/410 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.304); catalogued as rs782140216, COSV52218101; called by muse, mutect2, varscan2
- HTR4 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 151/336 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58791494; called by muse, mutect2, varscan2
- HYDIN | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV66636817; called by muse, mutect2, varscan2
- HYDIN | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267604623, COSV55485377; called by muse, mutect2, varscan2
- IGHJ3 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 185/346 reads (53%) | PolyPhen probably damaging (1); catalogued as rs561731097; called by muse, mutect2, varscan2
- IGLV8-61 | c.220A>C p.I74L | Missense Mutation (SNP) | VAF 199/320 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs1157862789; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.24A>C p.R8S | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.258); catalogued as rs901538036; called by muse, mutect2, varscan2
- ITGA2B | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 214/595 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52233948; called by muse, mutect2, varscan2
- ITGA4 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV67896643; called by muse, mutect2, varscan2
- ITPRID1 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 201/624 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1242666825; called by muse, mutect2, varscan2
- ITPRID1 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 199/620 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs962341198; called by muse, mutect2, varscan2
- KATNB1 | c.1134C>G p.N378K | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV65550878; called by muse, mutect2, varscan2
- KCNF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 232/579 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs773536391, COSV54462309, COSV54464047; called by muse, mutect2, varscan2
- KCNQ2 | c.2114C>T p.P705L (on ENST00000359125 / NM_172107.4; = p.P677L on NM_004518.6) | Missense Mutation (SNP) | VAF 216/765 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as rs779609892, CD162120, COSV60546961; called by muse, mutect2, varscan2
- KLHDC7B | c.1708C>T p.P570S (on ENST00000395676; = p.P1211S on NM_138433.5) | Missense Mutation (SNP) | VAF 295/498 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as rs539179395; called by muse, mutect2, varscan2
- KLHL1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 123/200 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV64767822; called by muse, mutect2, varscan2
- LCE1C | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 71/527 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1239075741, COSV100908484; called by muse, mutect2, varscan2
- LIPH | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 123/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565980022, COSV56183609; called by muse, mutect2, varscan2
- LRRC32 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 277/442 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747056345, COSV52631435, COSV52634094; called by muse, mutect2, varscan2
- MACF1 | c.7897C>T p.P2633S | Missense Mutation (SNP) | VAF 43/228 reads (19%) | catalogued as rs997195755, COSV57121546; called by muse, mutect2, varscan2
- MAP3K2 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778219189; called by muse, mutect2, varscan2
- MGAT3 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 315/476 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1471170304, COSV100362094; called by muse, mutect2, varscan2
- MSR1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 127/395 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs13306549, COSV50508538; called by muse, mutect2, varscan2
- MUC16 | c.37996C>T p.P12666S | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs762490369, COSV67481340, COSV67483000; called by muse, mutect2, varscan2
- MUC16 | c.34952C>T p.P11651L | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV67447805; called by muse, mutect2, varscan2
- MUC16 | c.26542G>A p.E8848K | Missense Mutation (SNP) | VAF 185/437 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs758682809, COSV67446748, COSV67446844; called by muse, mutect2, varscan2
- MUC16 | c.5489G>A p.W1830* | Nonsense Mutation (SNP) | VAF 188/470 reads (40%) | catalogued as rs865904726; called by muse, mutect2, varscan2
- MUC4 | c.13298G>A p.W4433* (on ENST00000463781 / NM_018406.7; = p.W197* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 79/473 reads (17%) | catalogued as COSV100205482; called by muse, mutect2, varscan2
- MYH3 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 162/452 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV56863100; called by muse, mutect2, varscan2
- MYH4 | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 141/433 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1451700052, COSV55119246; called by muse, mutect2, varscan2
- MYH4 | c.4339G>A p.D1447N | Missense Mutation (SNP) | VAF 122/386 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs751516938, COSV55117034; called by muse, mutect2, varscan2
- NBEA | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 149/231 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs996483510, COSV59771879; called by muse, mutect2, varscan2
- NCR1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 146/612 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as rs587662425, COSV52555744; called by muse, mutect2, varscan2
- NDC80 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs1311094033; called by muse, mutect2, varscan2
- NLRP8 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 169/356 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV52583825; called by muse, mutect2, varscan2
- NOVA1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57475853, COSV57490364; called by muse, mutect2, varscan2
- NSG2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 188/452 reads (42%) | SIFT tolerated (0.98); PolyPhen benign (0.16); catalogued as rs751261457; called by muse, mutect2, varscan2
- NYNRIN | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 94/463 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs751733364; called by muse, mutect2, varscan2
- OBSCN | c.14689G>A p.G4897R | Missense Mutation (SNP) | VAF 303/684 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1201748721; called by muse, mutect2, varscan2
- OPLAH | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 257/615 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782022628; called by muse, mutect2
- OR2A14 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 252/590 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs751416464; called by muse, varscan2
- OR2J1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 214/476 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs867275247; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 153/362 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2Z1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs782472476, COSV60691691; called by muse, mutect2, varscan2
- OR4K2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1288967692, COSV53849761; called by muse, mutect2, varscan2
- OR4M2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); catalogued as rs753440241; called by muse, mutect2, varscan2
- OR52E8 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs1320629304; called by muse, mutect2, varscan2
- OR5H6 | c.781C>T p.L261F (on ENST00000642105; = p.L245F on NM_001005479.2) | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.651); catalogued as COSV101051781; called by muse, mutect2
- OR6C4 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV67793117; called by muse, mutect2, varscan2
- OR6C4 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as COSV67792784; called by muse, mutect2, varscan2
- OR6C6 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV64456246; called by muse, mutect2, varscan2
- OR6C75 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV58551492; called by muse, mutect2, varscan2
- OSBPL1A | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs144234125; called by muse, mutect2, varscan2
- PAH | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1237673210, COSV61020808; called by muse, mutect2, varscan2
- PAK1IP1 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 182/387 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV65435203; called by muse, mutect2, varscan2
- PARD3B | c.681-1G>C p.X227_splice | Splice Site (SNP) | VAF 48/184 reads (26%) | catalogued as rs1420622205; called by muse, mutect2, varscan2
- PARD3B | c.681G>T p.R227S | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62533639; called by muse, mutect2, varscan2
- PCDH15 | c.4583G>A p.G1528E (on ENST00000644397 / NM_001354429.2; = p.G1477E on NM_001142769.3) | Missense Mutation (SNP) | VAF 114/202 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100905335; called by muse, mutect2, varscan2
- PCDH18 | c.1687G>C p.V563L | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV61269299; called by muse, mutect2, varscan2
- PCDHA8 | c.1855C>A p.R619S | Missense Mutation (SNP) | VAF 108/468 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs145175505, COSV65323207, COSV65332790; called by muse, mutect2, varscan2
- PCDHB1 | c.1975C>A p.L659I | Missense Mutation (SNP) | VAF 107/479 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV60633394; called by muse, mutect2, varscan2
- PCDHGB2 | c.2137C>A p.L713M | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV53963402; called by muse, mutect2, varscan2
- PCED1B | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV71395065; called by muse, mutect2, varscan2
- PCLO | c.3418C>T p.P1140S | Missense Mutation (SNP) | VAF 345/737 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs770134830, COSV61623858; called by muse, mutect2, varscan2
- PER3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs145870917; called by muse, mutect2, varscan2
- PIP5K1A | c.907G>A p.A303T (on ENST00000368888 / NM_001135638.2; = p.A290T on NM_003557.3) | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV62958114; called by muse, mutect2, varscan2
- PKD1L1 | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 271/751 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs758631112; called by muse, mutect2, varscan2
- PKHD1L1 | c.5621C>T p.S1874F | Missense Mutation (SNP) | VAF 111/430 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as COSV65749538; called by muse, mutect2, varscan2
- PKHD1L1 | c.7875G>A p.W2625* | Nonsense Mutation (SNP) | VAF 152/376 reads (40%) | catalogued as COSV65744537; called by muse, varscan2
- PLXNA1 | c.3686C>T p.S1229L | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs368565319, COSV99302009; called by muse, mutect2, varscan2
- PNPLA6 | c.1565C>T p.S522F (on ENST00000414982 / NM_001166111.2; = p.S474F on NM_006702.5) | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1351660925, COSV55379805; called by muse, mutect2, varscan2
- POLR2A | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 147/426 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775983104, COSV59493515; called by muse, mutect2, varscan2
- PRDM9 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 273/597 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1187228739, COSV99689805, COSV99689896; called by muse, mutect2, varscan2
- PRR12 | c.424G>A p.G142S (on ENST00000615927; = p.G963S on NM_020719.3) | Missense Mutation (SNP) | VAF 148/602 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746044633; called by muse, mutect2, varscan2
- PRR23C | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 123/548 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs757755275; called by muse, mutect2, varscan2
- PSMD2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs867093823; called by muse, mutect2, varscan2
- PTGIS | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 155/578 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747873847, COSV54835206; called by muse, mutect2, varscan2
- PTPRC | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 182/438 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758589060; called by muse, mutect2, varscan2
- PTPRK | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 87/385 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63887653, COSV63888133; called by muse, mutect2, varscan2
- PTPRZ1 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 256/756 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV66447127; called by muse, varscan2
- PZP | c.3774G>T p.Q1258H | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54371440; called by muse, mutect2, varscan2
- QARS1 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs1291965738, COSV100069983; called by muse, mutect2, varscan2
- R3HDM2 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 163/412 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as rs763160462, COSV60413936; called by muse, mutect2, varscan2
- RBMXL2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 298/479 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779687422, COSV100182168; called by muse, mutect2, varscan2
- RET | c.2139G>A p.E713= | Splice Region (SNP) | VAF 85/146 reads (58%) | catalogued as rs149460492; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHBDF1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1231239788, COSV51957098; called by muse, mutect2, varscan2
- RILP | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 146/441 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV53961325; called by muse, mutect2, varscan2
- RNF135 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 167/503 reads (33%) | catalogued as rs147042833, COSV60434366; called by muse, mutect2, varscan2
- RYR3 | c.4018C>T p.P1340S | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV66779483; called by muse, mutect2, varscan2
- SCN2A | c.5153G>A p.G1718E | Missense Mutation (SNP) | VAF 212/511 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51830509; called by muse, mutect2, varscan2
- SEMA3E | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 226/552 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748315427, COSV57088558; called by muse, mutect2, varscan2
- SGMS1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 167/296 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100693315; called by muse, mutect2, varscan2
- SHISA3 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 103/515 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59979830; called by muse, mutect2, varscan2
- SLC2A9 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs776808033; called by muse, mutect2, varscan2
- SLC35G2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 70/394 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs748228452, COSV67588367; called by muse, mutect2
- SP140 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as COSV59446076; called by muse, mutect2, varscan2
- SPANXN2 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 177/337 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV65129304; called by muse, mutect2, varscan2
- SPANXN2 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 181/341 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV65128301; called by muse, mutect2, varscan2
- SPATA16 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1350735686, COSV100651126; called by muse, mutect2, varscan2
- SPEG | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 114/598 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs895275228, COSV56664916; called by muse, varscan2
- SPOCD1 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 78/409 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99929662; called by muse, mutect2, varscan2
- SPTB | c.5365C>T p.R1789C | Missense Mutation (SNP) | VAF 105/505 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745688508; called by muse, mutect2, varscan2
- SRCAP | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 45/262 reads (17%) | catalogued as COSV99351198; called by muse, mutect2, varscan2
- ST18 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1016952385, COSV52494044; called by muse, mutect2, varscan2
- ST8SIA4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 150/334 reads (45%) | PolyPhen possibly damaging (0.908); catalogued as COSV51506333; called by muse, mutect2, varscan2
- SULT1C4 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs761566136; called by muse, mutect2, varscan2
- SULT4A1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 140/252 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs752151481, COSV99970480; called by muse, mutect2
- SYCP2L | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs768733116; called by muse, mutect2, varscan2
- SYNGR1 | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 286/435 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs748528372; called by muse, mutect2, varscan2
- TAL1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 108/485 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750834196, COSV53747247; called by muse, mutect2, varscan2
- TAS1R2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 95/427 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs752149652, COSV64744825, COSV64745499; called by muse, mutect2, varscan2
- TBC1D9 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs756151069, COSV71306981; called by muse, mutect2, varscan2
- TCHHL1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 193/585 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV64286694; called by muse, mutect2, varscan2
- TDRD15 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.065); catalogued as rs971473346; called by muse, mutect2, varscan2
- TECRL | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101168904; called by muse, mutect2, varscan2
- THSD7A | c.3881C>A p.P1294H | Missense Mutation (SNP) | VAF 70/646 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as COSV101439729, COSV69855823; called by muse, mutect2, varscan2
- THSD7B | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as COSV55657721; called by muse, mutect2, varscan2
- THSD7B | c.2063G>A p.W688* | Nonsense Mutation (SNP) | VAF 68/386 reads (18%) | catalogued as COSV99745458; called by muse, mutect2, varscan2
- TINAG | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52506774; called by muse, mutect2, varscan2
- TLE2 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 143/330 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772980855, COSV53582162; called by muse, varscan2
- TMEM132C | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 139/331 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs760430113; called by muse, mutect2, varscan2
- TMEM63C | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 158/419 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368880696; called by muse, mutect2, varscan2
- TMPO | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV54122116; called by muse, mutect2, varscan2
- TP53 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 137/423 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs909643864, COSV52712660, COSV53743131; called by muse, mutect2, varscan2
- TRIM50 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 255/778 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1290156764, COSV53093688, COSV53094227; called by muse, varscan2
- TXNDC11 | c.1574C>T p.S525F (on ENST00000356957 / NM_001303447.2; = p.S498F on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/418 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51601352; called by muse, mutect2, varscan2
- UNC80 | c.3881G>A p.G1294E | Missense Mutation (SNP) | VAF 62/339 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV55885191; called by muse, mutect2, varscan2
- VAV1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 147/319 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs527259397, COSV58382638; called by muse, mutect2, varscan2
- XIRP1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 172/420 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV61138647; called by muse, mutect2, varscan2
- ZBBX | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs750732013, COSV56787033; called by muse, mutect2, varscan2
- ZBTB40 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765006255; called by muse, mutect2, varscan2
- ZFP42 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs1386358200, COSV58817351; called by muse, mutect2, varscan2
- ZFP57 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 429/858 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65305802; called by muse, mutect2, varscan2
- ZMYND8 | c.2363C>T p.T788M (on ENST00000311275 / NM_001363741.2; = p.T808M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/754 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.336); catalogued as rs778381613, COSV53694802; called by muse, mutect2, varscan2
- ZNF462 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 159/294 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs745724742, COSV52936186; called by muse, mutect2, varscan2
- ZNF534 | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 92/259 reads (36%) | catalogued as rs1451540106; called by muse, mutect2, varscan2
- ZNF761 | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV61889711; called by muse, mutect2, varscan2
- ZNF790 | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV63212371, COSV63212763; called by muse, mutect2, varscan2
- ZNF800 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 165/489 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs1157540569, COSV56174842; called by muse, mutect2, varscan2
- ZNF804A | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 126/274 reads (46%) | catalogued as rs1300852164, COSV56433664; called by muse, mutect2, varscan2
- ZNF98 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 69/512 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63339629; called by muse, mutect2, varscan2
- ZNHIT6 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs774638871, COSV100995691; called by muse, mutect2, varscan2
- ZP1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 76/442 reads (17%) | catalogued as rs201997227, COSV53923884; called by muse, mutect2, varscan2
- ZP2 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs780248419; called by muse, mutect2, varscan2
- A1CF | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 188/298 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ABAT | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ABHD17A | c.473C>T p.S158F (on ENST00000292577 / NM_001130111.2; = p.S209F on NM_031213.4) | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- AC126283.2 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.019); called by muse, varscan2
- AC242842.3 | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 72/426 reads (17%) | called by muse, mutect2, varscan2
- ACOXL | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR1 | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADAM32 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADAMDEC1 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.097); called by muse, mutect2
- ADAMTS6 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ADCY7 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHSP | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALPK3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 175/420 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALS2CL | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 127/299 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANGPT1 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANGPTL5 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 125/342 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ANKRD11 | c.3716C>T p.P1239L | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANKRD12 | c.5527A>G p.R1843G | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD18A | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD62 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ANKRD66 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 165/519 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- APBB1IP | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 196/372 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- APEH | c.1958A>G p.D653G | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2
- APOBEC3A | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 229/359 reads (64%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARSF | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 176/300 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATN1 | c.683T>A p.L228* | Nonsense Mutation (SNP) | VAF 79/327 reads (24%) | called by muse, mutect2, varscan2
- ATP8A1 | c.1001-1_1001del p.X334_splice | Splice Site (DEL) | VAF 29/208 reads (14%) | called by mutect2, pindel, varscan2
- BCL6B | c.871C>G p.R291G | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BDKRB1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 95/532 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- BDP1 | c.4621C>T p.Q1541* | Nonsense Mutation (SNP) | VAF 78/423 reads (18%) | called by muse, mutect2, varscan2
- BMP2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 231/524 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BOD1L1 | c.6817C>T p.P2273S | Missense Mutation (SNP) | VAF 214/452 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- BPIFB2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 200/446 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C10orf71 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 245/405 reads (60%) | SIFT tolerated (0.79); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CAMSAP3 | c.3179A>C p.H1060P | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.10751C>T p.S3584L | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCDC73 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CD86 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CDH18 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 92/471 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CDH5 | c.1131C>A p.Y377* | Nonsense Mutation (SNP) | VAF 66/370 reads (18%) | called by muse, mutect2, varscan2
- CDHR2 | c.3910G>A p.G1304S | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CHAMP1 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 301/474 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CHD7 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 152/383 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CHPF2 | c.2146C>T p.L716F | Missense Mutation (SNP) | VAF 353/833 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CHSY3 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CIAO3 | c.1035G>A p.R345= | Splice Region (SNP) | VAF 46/232 reads (20%) | called by muse, mutect2, varscan2
- CNTN4 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COBL | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 105/757 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL1A1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 78/483 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- COL28A1 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 158/474 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL4A4 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.335A>T p.K112M | Missense Mutation (SNP) | VAF 92/257 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- COL6A5 | c.6205C>T p.L2069F (on ENST00000312481; = p.L2065F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- COL7A1 | c.8257G>A p.V2753M | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- COQ8A | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 224/697 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF1R | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CSNKA2IP | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP2C9 | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 106/390 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP8B1 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DACT2 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 95/396 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCAF12L2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 153/503 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DGKB | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 260/563 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DHRS7C | c.498G>A p.M166I (on ENST00000330255 / NM_001220493.2; = p.M165I on NM_001105571.3) | Missense Mutation (SNP) | VAF 113/344 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- DNAH7 | c.6226A>C p.K2076Q | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- DNAI2 | c.1268T>A p.F423Y | Missense Mutation (SNP) | VAF 175/463 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DNAL1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DROSHA | c.2038C>T p.H680Y | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- DSG1 | c.2585T>A p.V862E | Missense Mutation (SNP) | VAF 180/420 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DST | c.10403C>T p.P3468L | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DST | c.4186A>T p.I1396F (on ENST00000361203 / NM_001374722.1; = p.I1070F on NM_001723.6) | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- DYNC2I1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 232/561 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DYSF | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 77/366 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECM2 | c.1133A>T p.N378I | Missense Mutation (SNP) | VAF 116/202 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2
- EFCAB5 | c.2938A>T p.K980* | Nonsense Mutation (SNP) | VAF 159/475 reads (33%) | called by muse, mutect2, varscan2
- ELAPOR1 | c.2460C>A p.C820* | Nonsense Mutation (SNP) | VAF 144/377 reads (38%) | called by muse, mutect2, varscan2
- ELMO2 | c.246C>T p.S82= | Splice Region (SNP) | VAF 93/316 reads (29%) | called by muse, mutect2, varscan2
- ENKUR | c.281A>C p.H94P | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPG5 | c.5206C>T p.P1736S | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA6 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 176/354 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- EPN3 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERCC6 | c.2515G>T p.G839W | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERV3-1 | c.1666T>G p.Y556D | Missense Mutation (SNP) | VAF 177/639 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EXT1 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAT1 | c.2000A>C p.H667P | Missense Mutation (SNP) | VAF 97/400 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.12961G>A p.E4321K | Missense Mutation (SNP) | VAF 175/288 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FLG | c.8545G>A p.D2849N | Missense Mutation (SNP) | VAF 84/1634 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); called by muse, mutect2
- FREM1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- FSIP1 | c.752A>C p.N251T | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- GALNT17 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCLM | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 119/277 reads (43%) | called by muse, mutect2, varscan2
- GGCX | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 82/399 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGCX | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 82/399 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 145/349 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GLYATL3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 92/554 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GNPTG | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 133/329 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GP5 | c.383T>A p.F128Y | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GPR141 | c.711T>A p.C237* | Nonsense Mutation (SNP) | VAF 228/698 reads (33%) | called by muse, mutect2, varscan2
- HCFC1 | c.518T>C p.L173S | Missense Mutation (SNP) | VAF 155/286 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HEATR5B | c.4876_4881del p.Y1626_A1627del | In Frame Del (DEL) | VAF 50/254 reads (20%) | called by mutect2, pindel, varscan2
- HEPH | c.2609C>A p.P870H (on ENST00000343002; = p.P603H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHIPL2 | c.1350T>G p.F450L | Missense Mutation (SNP) | VAF 252/576 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- HJV | c.685G>A p.E229K (on ENST00000336751 / NM_213653.4; = p.E116K on NM_145277.5) | Missense Mutation (SNP) | VAF 127/461 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HKDC1 | c.1619T>A p.V540D | Missense Mutation (SNP) | VAF 182/314 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOOK1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HTR4 | c.1028C>G p.T343S | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- HTR4 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 222/467 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HYOU1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGHV1-3 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 212/402 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1550G>A p.G517E | Missense Mutation (SNP) | VAF 197/349 reads (56%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- IPCEF1 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN1 | c.5018-1G>A p.X1673_splice | Splice Site (SNP) | VAF 54/219 reads (25%) | called by muse, mutect2, varscan2
- KCNH7 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNV1 | c.767A>T p.E256V | Missense Mutation (SNP) | VAF 150/485 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF4B | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 86/433 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KIR3DL3 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL23 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRT71 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 81/407 reads (20%) | called by muse, mutect2, varscan2
- LGALS14 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LILRB1 | c.2069C>T p.A690V (on ENST00000427581; = p.A639V on NM_006669.6) | Missense Mutation (SNP) | VAF 163/419 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LNPEP | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP1B | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, varscan2
- LRRC71 | c.1454C>G p.T485R | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LRRIQ1 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- LRTM1 | c.404G>C p.S135T | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MALRD1 | c.2022G>A p.W674* | Nonsense Mutation (SNP) | VAF 168/290 reads (58%) | called by muse, mutect2, varscan2
- MAST4 | c.1519G>A p.G507R (on ENST00000403625 / NM_001164664.2; = p.G318R on NM_015183.3) | Missense Mutation (SNP) | VAF 174/397 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 184/329 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MDGA1 | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 74/564 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MED23 | c.870T>A p.N290K | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MELTF | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- MICAL2 | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 99/453 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLXIP | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 77/397 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MLXIPL | c.211T>A p.S71T | Missense Mutation (SNP) | VAF 382/820 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMP25 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 95/590 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MORC1 | c.1025A>T p.K342I | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRC2 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 103/477 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTMR3 | c.3032C>T p.S1011F | Missense Mutation (SNP) | VAF 276/435 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MUC2 | c.3770C>T p.S1257F | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, varscan2
- MUCL3 | c.1316G>A p.G439E (on ENST00000304311; = p.G1315E on NM_080870.4) | Missense Mutation (SNP) | VAF 237/809 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MVD | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- MYH4 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 132/371 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NACA | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 66/314 reads (21%) | called by muse, mutect2, varscan2
- NCOA7 | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NID1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2
- NLRP1 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 101/373 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NLRP4 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NLRP8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 151/340 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NPFFR2 | c.1301T>G p.I434S | Missense Mutation (SNP) | VAF 186/419 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NRG1 | c.925G>A p.V309M (on ENST00000405005 / NM_013964.5; = p.V314M on NM_013956.5) | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.10184A>G p.K3395R | Missense Mutation (SNP) | VAF 189/618 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OPRL1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 309/720 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- OR11L1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 213/696 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- OR1E2 | c.908A>T p.N303I | Missense Mutation (SNP) | VAF 162/428 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR1L8 | c.267A>T p.E89D | Missense Mutation (SNP) | VAF 128/238 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2A7 | c.764T>A p.I255N | Missense Mutation (SNP) | VAF 302/1294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- OR2M5 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 66/575 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR51B2 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- OR51B2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5AU1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 214/458 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- PAK5 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 275/576 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- PAM | c.1814T>A p.L605Q | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARD3B | c.3094G>A p.E1032K (on ENST00000406610 / NM_001302769.2; = p.E963K on NM_057177.7) | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PCDHB9 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHGA6 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 143/354 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGB2 | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 55/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCED1B | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 112/499 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PDCL3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PERM1 | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 222/490 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGS1 | c.763T>C p.C255R | Missense Mutation (SNP) | VAF 221/577 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- PHOX2B | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 173/413 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.2312C>T p.S771F (on ENST00000676171; = p.S730F on NM_004570.5) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIK3C2G | c.3367del p.I1123Lfs*33 (on ENST00000676171; = p.I1082Lfs*33 on NM_004570.5) | Frame Shift Del (DEL) | VAF 66/288 reads (23%) | called by mutect2, pindel, varscan2
- PKDREJ | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 204/360 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKHD1L1 | c.3653C>T p.S1218L | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PKHD1L1 | c.4394-1G>A p.X1465_splice | Splice Site (SNP) | VAF 73/186 reads (39%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.8057A>G p.K2686R | Missense Mutation (SNP) | VAF 133/368 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- PLBD2 | c.462G>C p.R154S | Missense Mutation (SNP) | VAF 80/354 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PLCB1 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PLCZ1 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PLEKHB2 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 68/205 reads (33%) | PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- POM121L2 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 155/544 reads (28%) | called by muse, varscan2
- PRAMEF14 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- PRKACG | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 169/299 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKCSH | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 92/235 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PROZ | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 256/383 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PTBP3 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 143/278 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PTPRO | c.76-1G>A p.X26_splice | Splice Site (SNP) | VAF 64/175 reads (37%) | called by muse, mutect2, varscan2
- PUS7 | c.390A>T p.L130F | Missense Mutation (SNP) | VAF 220/417 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PYGO2 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 336/766 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RASIP1 | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 145/395 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.8377T>G p.C2793G | Missense Mutation (SNP) | VAF 94/757 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SAMSN1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SCAMP3 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 207/762 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SEMA3D | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 239/526 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SERPINA10 | c.206T>A p.M69K | Missense Mutation (SNP) | VAF 258/527 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB1 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SETBP1 | c.4099G>A p.V1367I | Missense Mutation (SNP) | VAF 77/434 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEZ6 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SGCZ | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, varscan2
- SH3RF1 | c.2133T>A p.D711E | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- SH3YL1 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHROOM1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SIGLEC1 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 166/623 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SIPA1L1 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 155/435 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SLC12A2 | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC13A3 | c.1655A>G p.N552S | Missense Mutation (SNP) | VAF 195/468 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC30A8 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC43A1 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 68/352 reads (19%) | called by muse, mutect2, varscan2
- SLIT2 | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SMARCAD1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SMARCAL1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SMG9 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SORBS2 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SOX11 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 151/386 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SPEM3 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 133/370 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SPHKAP | c.3427G>A p.G1143R | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- STEAP2 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 195/573 reads (34%) | called by muse, mutect2, varscan2
- STING1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- STXBP5L | c.811_812del p.D271Wfs*2 | Frame Shift Del (DEL) | VAF 107/253 reads (42%) | called by mutect2, pindel, varscan2
- SYT17 | c.1261T>C p.F421L | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TARBP1 | c.604T>A p.C202S | Missense Mutation (SNP) | VAF 115/767 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D15 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBCC | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 145/448 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- TDRD6 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 154/433 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM1 | c.3810A>C p.K1270N | Missense Mutation (SNP) | VAF 193/346 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- TET2 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TFAP2D | c.1310A>T p.K437I | Missense Mutation (SNP) | VAF 141/434 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TFEC | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 165/376 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by mutect2, varscan2
- TGM7 | c.9G>A p.Q3= | Splice Region (SNP) | VAF 129/256 reads (50%) | called by muse, mutect2, varscan2
- THRB | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 162/339 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TINAG | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TLE4 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 152/304 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TLR5 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 64/548 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TMED8 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM270 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 411/848 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM82 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 163/419 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TOGARAM1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 176/439 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TPTE | c.1262T>A p.I421N (on ENST00000618007 / NM_199261.4; = p.I403N on NM_199259.4) | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRPC4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TRPM8 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TRPV5 | c.2020G>T p.G674W | Missense Mutation (SNP) | VAF 460/985 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TRRAP | c.8795C>T p.P2932L (on ENST00000359863 / NM_001244580.1; = p.P2914L on NM_003496.3) | Missense Mutation (SNP) | VAF 184/573 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- TSPAN13 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 140/442 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- TTN | c.56302G>A p.E18768K (on ENST00000591111; = p.E11344K on NM_003319.4) | Missense Mutation (SNP) | VAF 76/301 reads (25%) | PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TTN | c.46508C>T p.P15503L (on ENST00000591111; = p.P8079L on NM_003319.4) | Missense Mutation (SNP) | VAF 46/265 reads (17%) | PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TUBG1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 201/555 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR4 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USP33 | c.479del p.T160Ifs*12 | Frame Shift Del (DEL) | VAF 44/248 reads (18%) | called by pindel, varscan2
- USP33 | c.449T>G p.F150C | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.408); called by muse, varscan2
- VGLL2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- VSTM1 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 147/339 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- VWA5B2 | c.841A>C p.M281L | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNT2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 317/701 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP1 | c.2995G>A p.G999R | Missense Mutation (SNP) | VAF 127/620 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZC3H12C | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZCCHC7 | c.1243T>G p.Y415D | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZFPM2 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 147/366 reads (40%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ZNF234 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 139/375 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ZNF253 | c.956A>T p.K319I | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ZNF30 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF407 | c.6104C>T p.P2035L | Missense Mutation (SNP) | VAF 213/530 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF564 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF66 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF862 | c.3113G>A p.C1038Y | Missense Mutation (SNP) | VAF 93/876 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF91 | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5A | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 106/491 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ABCB5 | c.1731C>T p.I577= (on ENST00000404938 / NM_001163941.2; = p.I132= on NM_178559.6) | Silent (SNP) | VAF 177/548 reads (32%) | catalogued as rs149931729; called by muse, mutect2, varscan2
- ABCB8 | c.1678C>T p.L560= (on ENST00000297504 / NM_001282291.2; = p.L543= on NM_007188.5) | Silent (SNP) | VAF 42/469 reads (9%) | catalogued as COSV99874999; called by muse, mutect2
- AC097637.1 | c.24G>A p.L8= | Silent (SNP) | VAF 88/388 reads (23%) | called by muse, mutect2, varscan2
- ACTR3B | c.1039C>T p.L347= | Silent (SNP) | VAF 212/501 reads (42%) | called by muse, mutect2, varscan2
- ADAM18 | c.96G>A p.K32= | Silent (SNP) | VAF 134/390 reads (34%) | catalogued as COSV55857027, COSV99695021; called by muse, mutect2, varscan2
- ADAM30 | c.2100C>T p.I700= | Silent (SNP) | VAF 92/416 reads (22%) | called by muse, mutect2, varscan2
- ADAR | c.3120C>A p.I1040= | Silent (SNP) | VAF 249/544 reads (46%) | catalogued as COSV52712679; called by muse, mutect2, varscan2
- ADCY8 | c.2229C>T p.I743= | Silent (SNP) | VAF 157/346 reads (45%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4287G>A p.L1429= (on ENST00000506720 / NM_001322402.2; = p.L1318= on NM_015236.6) | Silent (SNP) | VAF 86/423 reads (20%) | catalogued as rs989510567; called by muse, mutect2, varscan2
- AFM | c.1731G>A p.V577= | Silent (SNP) | VAF 80/412 reads (19%) | called by muse, mutect2, varscan2
- ALG10 | c.1254C>T p.F418= | Silent (SNP) | VAF 50/348 reads (14%) | catalogued as rs1355210406; called by muse, mutect2, varscan2
- ALOX12B | c.1107C>T p.F369= | Silent (SNP) | VAF 154/450 reads (34%) | catalogued as rs181293386; called by muse, mutect2, varscan2
- ANKRD31 | c.5319G>A p.K1773= | Silent (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- AQP1 | c.654C>T p.I218= | Silent (SNP) | VAF 186/539 reads (35%) | catalogued as rs375975852; called by muse, mutect2, varscan2
- ARHGAP22 | c.1644C>T p.A548= | Silent (SNP) | VAF 214/378 reads (57%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.126C>T p.F42= | Silent (SNP) | VAF 74/371 reads (20%) | catalogued as rs772729752, COSV68334760; called by muse, mutect2, varscan2
- ARHGEF5 | c.2532C>T p.I844= | Silent (SNP) | VAF 124/775 reads (16%) | called by muse, varscan2
- ASIC4 | c.1065C>T p.P355= (on ENST00000347842 / NM_182847.3; = p.P374= on NM_018674.6) | Silent (SNP) | VAF 142/392 reads (36%) | called by muse, varscan2
- AXDND1 | c.429G>A p.K143= | Silent (SNP) | VAF 178/398 reads (45%) | catalogued as COSV100858336; called by muse, mutect2
- AZGP1 | c.699G>A p.G233= | Silent (SNP) | VAF 209/658 reads (32%) | catalogued as rs1169120118; called by muse, mutect2, varscan2
- BBS10 | c.588C>T p.D196= | Silent (SNP) | VAF 134/332 reads (40%) | called by muse, mutect2, varscan2
- BNIP2 | c.735C>T p.I245= | Silent (SNP) | VAF 105/283 reads (37%) | catalogued as COSV51109203; called by muse, mutect2, varscan2
- BTBD7 | c.489G>A p.R163= | Silent (SNP) | VAF 98/475 reads (21%) | called by muse, mutect2, varscan2
- BTN3A2 | c.303G>A p.R101= | Silent (SNP) | VAF 59/659 reads (9%) | called by muse, mutect2, varscan2
- C20orf202 | c.114G>A p.L38= | Silent (SNP) | VAF 183/402 reads (46%) | catalogued as rs1278889226; called by muse, mutect2, varscan2
- C6orf62 | c.507C>T p.I169= | Silent (SNP) | VAF 206/481 reads (43%) | catalogued as rs760728809; called by muse, mutect2, varscan2
- CACNA1E | c.5028G>A p.K1676= | Silent (SNP) | VAF 183/716 reads (26%) | called by muse, mutect2, varscan2
- CACNA1G | c.3708C>T p.V1236= | Silent (SNP) | VAF 128/373 reads (34%) | called by muse, mutect2, varscan2
- CAMKK2 | c.787C>T p.L263= | Silent (SNP) | VAF 82/472 reads (17%) | called by muse, mutect2, varscan2
- CAMKV | c.318G>A p.E106= | Silent (SNP) | VAF 123/284 reads (43%) | catalogued as rs545456418, COSV99615817; called by muse, mutect2, varscan2
- CCDC144A | c.1539C>T p.F513= | Silent (SNP) | VAF 78/276 reads (28%) | catalogued as COSV100138656; called by muse, mutect2, varscan2
- CCDC170 | c.1201T>C p.L401= | Silent (SNP) | VAF 83/306 reads (27%) | called by muse, mutect2, varscan2
- CDH17 | c.2232C>T p.I744= | Silent (SNP) | VAF 124/320 reads (39%) | catalogued as COSV50330863; called by muse, mutect2, varscan2
- CDH20 | c.354C>T p.A118= | Silent (SNP) | VAF 110/421 reads (26%) | called by muse, mutect2, varscan2
- CDH23 | c.4728C>T p.F1576= | Silent (SNP) | VAF 93/346 reads (27%) | called by muse, mutect2, varscan2
- CDHR2 | c.2814C>T p.I938= | Silent (SNP) | VAF 171/408 reads (42%) | catalogued as rs777087575, COSV56135295; called by muse, mutect2, varscan2
- CDKAL1 | c.48C>T p.I16= | Silent (SNP) | VAF 169/429 reads (39%) | catalogued as rs199754503; called by muse, mutect2, varscan2
- CEACAM20 | c.1482G>A p.P494= | Silent (SNP) | VAF 66/321 reads (21%) | catalogued as rs752971964, COSV57601367; called by muse, mutect2, varscan2
- CFAP47 | c.4560C>T p.F1520= | Silent (SNP) | VAF 124/222 reads (56%) | catalogued as rs868480054; called by muse, mutect2, varscan2
- CFAP57 | c.3621G>A p.Q1207= (on ENST00000372492 / NM_001378189.1; = p.Q1240= on NM_001195831.3) | Silent (SNP) | VAF 74/355 reads (21%) | called by muse, mutect2, varscan2
- CHD1L | c.837C>T p.Y279= | Silent (SNP) | VAF 243/571 reads (43%) | called by muse, mutect2, varscan2
- CHP1 | c.240C>T p.F80= | Silent (SNP) | VAF 132/246 reads (54%) | catalogued as rs761419711; called by muse, mutect2, varscan2
- CHST1 | c.156C>T p.T52= | Silent (SNP) | VAF 328/513 reads (64%) | catalogued as COSV57323472; called by muse, mutect2, varscan2
- CNBD1 | c.729C>T p.N243= | Silent (SNP) | VAF 94/321 reads (29%) | catalogued as COSV72976114; called by muse, mutect2, varscan2
- CNGA2 | c.1470G>A p.E490= | Silent (SNP) | VAF 215/414 reads (52%) | called by muse, mutect2, varscan2
- COL12A1 | c.2418A>T p.G806= | Silent (SNP) | VAF 52/281 reads (19%) | called by muse, mutect2, varscan2
- COL18A1 | c.198C>T p.P66= | Silent (SNP) | VAF 214/484 reads (44%) | called by muse, mutect2, varscan2
- COL19A1 | c.1182G>A p.G394= | Silent (SNP) | VAF 129/371 reads (35%) | catalogued as rs1174521030, COSV100507159, COSV100507488; called by muse, mutect2, varscan2
- COQ8A | c.267C>T p.A89= | Silent (SNP) | VAF 223/696 reads (32%) | called by muse, mutect2, varscan2
- CRB1 | c.1239G>A p.E413= | Silent (SNP) | VAF 90/614 reads (15%) | called by muse, mutect2, varscan2
- CSMD2 | c.2733C>T p.F911= | Silent (SNP) | VAF 64/292 reads (22%) | catalogued as COSV53960856; called by muse, mutect2, varscan2
- CSNK1G2 | c.561C>T p.I187= | Silent (SNP) | VAF 84/389 reads (22%) | catalogued as rs1180924167, COSV55335844, COSV55339935; called by muse, mutect2, varscan2
- DAB1 | c.849G>A p.G283= (on ENST00000371231; = p.G250= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 133/322 reads (41%) | catalogued as COSV100976341, COSV64694301; called by muse, mutect2, varscan2
- DAOA | c.90G>A p.R30= | Silent (SNP) | VAF 70/206 reads (34%) | catalogued as rs868491215; called by muse, mutect2, varscan2
- DCLK3 | c.1245G>A p.V415= | Silent (SNP) | VAF 67/377 reads (18%) | called by muse, mutect2, varscan2
- DCP1B | c.297C>T p.F99= | Silent (SNP) | VAF 89/347 reads (26%) | called by muse, mutect2, varscan2
- DCST2 | c.639C>T p.F213= | Silent (SNP) | VAF 211/510 reads (41%) | catalogued as rs562006776, COSV55052897; called by muse, mutect2, varscan2
- DENND2A | c.1530C>T p.N510= | Silent (SNP) | VAF 160/546 reads (29%) | called by muse, mutect2, varscan2
- DGLUCY | c.495G>A p.T165= | Silent (SNP) | VAF 174/389 reads (45%) | catalogued as rs374015135; called by muse, mutect2, varscan2
- DNAJC7 | c.1156C>T p.L386= | Silent (SNP) | VAF 182/529 reads (34%) | called by muse, mutect2, varscan2
- DOCK3 | c.2533C>T p.L845= | Silent (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- DSG1 | c.1935G>T p.L645= | Silent (SNP) | VAF 62/346 reads (18%) | catalogued as COSV57138358; called by mutect2, varscan2
- DUOX2 | c.348G>A p.V116= | Silent (SNP) | VAF 256/407 reads (63%) | catalogued as COSV100545734; called by muse, mutect2, varscan2
- DYTN | c.100T>C p.L34= | Silent (SNP) | VAF 83/207 reads (40%) | called by muse, mutect2, varscan2
- ELK3 | c.906C>A p.P302= | Silent (SNP) | VAF 159/449 reads (35%) | catalogued as rs1354382864; called by muse, mutect2, varscan2
- ENGASE | c.708C>T p.I236= | Silent (SNP) | VAF 89/278 reads (32%) | catalogued as rs751846454; called by muse, mutect2, varscan2
- ENPP1 | c.1581G>A p.R527= | Silent (SNP) | VAF 49/202 reads (24%) | called by muse, mutect2, varscan2
- EPHA8 | c.1425C>T p.I475= | Silent (SNP) | VAF 52/290 reads (18%) | called by muse, mutect2, varscan2
- FAM135B | c.2485C>T p.L829= | Silent (SNP) | VAF 23/420 reads (5%) | catalogued as rs1217606952; called by muse, mutect2
- FBXO31 | c.624C>T p.Y208= | Silent (SNP) | VAF 57/248 reads (23%) | catalogued as rs780291715, COSV61149800; called by muse, mutect2, varscan2
- FER1L5 | c.3078G>A p.R1026= | Silent (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- FHL3 | c.684C>T p.I228= | Silent (SNP) | VAF 42/272 reads (15%) | catalogued as rs774143566, COSV65952575; called by muse, mutect2, varscan2
- FKBP6 | c.234G>A p.R78= | Silent (SNP) | VAF 295/591 reads (50%) | called by muse, mutect2, varscan2
- FRMPD2 | c.2829C>T p.I943= | Silent (SNP) | VAF 97/196 reads (49%) | catalogued as COSV59715507; called by muse, mutect2, varscan2
- FSIP2 | c.16356C>T p.T5452= | Silent (SNP) | VAF 115/347 reads (33%) | called by muse, mutect2, varscan2
- GALR1 | c.540C>T p.R180= | Silent (SNP) | VAF 114/454 reads (25%) | called by muse, mutect2, varscan2
- GAS7 | c.810C>T p.S270= (on ENST00000432992 / NM_201433.2; = p.S130= on NM_003644.3) | Silent (SNP) | VAF 145/398 reads (36%) | called by muse, mutect2, varscan2
- GCGR | c.1107G>A p.T369= | Silent (SNP) | VAF 175/514 reads (34%) | catalogued as rs528390403; called by muse, mutect2, varscan2
- GCKR | c.1848C>A p.P616= | Silent (SNP) | VAF 67/340 reads (20%) | called by muse, mutect2, varscan2
- GFOD2 | c.219C>T p.I73= | Silent (SNP) | VAF 83/445 reads (19%) | called by muse, mutect2, varscan2
- GLP2R | c.435G>A p.T145= | Silent (SNP) | VAF 110/382 reads (29%) | catalogued as rs145225948; called by muse, mutect2, varscan2
- GPR141 | c.459C>T p.S153= | Silent (SNP) | VAF 327/749 reads (44%) | called by muse, mutect2, varscan2
- GRID2IP | c.3561C>T p.F1187= | Silent (SNP) | VAF 124/428 reads (29%) | catalogued as rs1017118376, COSV70694153; called by muse, mutect2, varscan2
- HECW2 | c.2466G>A p.R822= | Silent (SNP) | VAF 62/303 reads (20%) | catalogued as COSV53651221; called by muse, mutect2, varscan2
- HLA-DOA | c.744C>T p.V248= | Silent (SNP) | VAF 126/424 reads (30%) | catalogued as COSV100008104; called by muse, mutect2, varscan2
- HS6ST3 | c.1335G>A p.R445= | Silent (SNP) | VAF 266/416 reads (64%) | catalogued as COSV65001697; called by muse, mutect2, varscan2
- HSPB9 | c.78G>A p.R26= | Silent (SNP) | VAF 167/456 reads (37%) | called by muse, mutect2, varscan2
- HYDIN | c.7851C>T p.I2617= | Silent (SNP) | VAF 26/205 reads (13%) | catalogued as COSV59260742; called by muse, mutect2, varscan2
- IGHV1-2 | c.66G>A p.Q22= | Silent (SNP) | VAF 102/561 reads (18%) | catalogued as rs182256840; called by muse, mutect2, varscan2
- IL1RAP | c.1488C>T p.I496= | Silent (SNP) | VAF 149/387 reads (39%) | catalogued as COSV50767174; called by muse, mutect2, varscan2
- IL6ST | c.2454C>T p.N818= | Silent (SNP) | VAF 57/371 reads (15%) | called by muse, mutect2, varscan2
- KCNA2 | c.561C>T p.I187= | Silent (SNP) | VAF 183/426 reads (43%) | called by muse, mutect2, varscan2
- KCNC3 | c.366G>A p.A122= | Silent (SNP) | VAF 94/478 reads (20%) | called by muse, mutect2, varscan2
- KCNH5 | c.2859C>A p.P953= | Silent (SNP) | VAF 111/409 reads (27%) | catalogued as COSV59776978; called by muse, mutect2, varscan2
- KCNK10 | c.747G>A p.T249= | Silent (SNP) | VAF 102/464 reads (22%) | catalogued as rs780510535, COSV100067470, COSV56639686; called by muse, varscan2
- KDM5A | c.2160C>T p.Y720= | Silent (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- KRT12 | c.1401C>T p.T467= | Silent (SNP) | VAF 139/398 reads (35%) | catalogued as rs1328445275; called by muse, mutect2, varscan2
- LAG3 | c.696C>T p.S232= | Silent (SNP) | VAF 114/414 reads (28%) | called by muse, mutect2, varscan2
- LAMA1 | c.4752C>T p.I1584= | Silent (SNP) | VAF 63/381 reads (17%) | catalogued as rs267605255; called by muse, mutect2, varscan2
- LGALS14 | c.108G>A p.L36= | Silent (SNP) | VAF 54/264 reads (20%) | called by muse, mutect2, varscan2
- LILRA2 | c.864C>T p.S288= | Silent (SNP) | VAF 252/648 reads (39%) | catalogued as COSV52191576; called by muse, varscan2
- LILRB3 | c.414G>A p.G138= | Silent (SNP) | VAF 125/1134 reads (11%) | catalogued as rs1458918866; called by muse, varscan2
- LMX1A | c.846G>T p.G282= | Silent (SNP) | VAF 163/491 reads (33%) | called by muse, mutect2, varscan2
- LRP1B | c.9387G>A p.L3129= | Silent (SNP) | VAF 53/343 reads (15%) | catalogued as rs1432038864; called by muse, mutect2, varscan2
- LRRC4C | c.135G>A p.Q45= | Silent (SNP) | VAF 180/385 reads (47%) | catalogued as COSV53427003, COSV53435977; called by muse, mutect2, varscan2
- LRRTM4 | c.558G>A p.L186= | Silent (SNP) | VAF 56/316 reads (18%) | called by muse, mutect2, varscan2
- MACC1 | c.1476C>A p.P492= | Silent (SNP) | VAF 71/645 reads (11%) | called by muse, mutect2, varscan2
- MAGI1 | c.4143G>A p.R1381= | Silent (SNP) | VAF 115/533 reads (22%) | called by muse, mutect2, varscan2
- MAML3 | c.2142C>T p.G714= | Silent (SNP) | VAF 99/497 reads (20%) | catalogued as rs546915831; called by muse, mutect2, varscan2
- MAP3K10 | c.1299C>T p.I433= | Silent (SNP) | VAF 219/497 reads (44%) | catalogued as COSV53420605; called by muse, mutect2, varscan2
- MAST4 | c.5544G>A p.G1848= (on ENST00000403625 / NM_001164664.2; = p.G1659= on NM_015183.3) | Silent (SNP) | VAF 94/375 reads (25%) | catalogued as rs1561204735; called by muse, mutect2, varscan2
- MCCC2 | c.1212T>A p.I404= | Silent (SNP) | VAF 59/224 reads (26%) | called by muse, mutect2, varscan2
- MCTP1 | c.1029C>T p.A343= | Silent (SNP) | VAF 96/236 reads (41%) | catalogued as rs142378017; called by muse, mutect2, varscan2
- MED1 | c.153T>C p.S51= | Silent (SNP) | VAF 156/437 reads (36%) | called by muse, mutect2, varscan2
- MLN | c.78C>T p.F26= | Silent (SNP) | VAF 96/390 reads (25%) | catalogued as COSV56475844; called by muse, mutect2, varscan2
- MTF1 | c.2166C>T p.S722= | Silent (SNP) | VAF 77/332 reads (23%) | called by muse, mutect2, varscan2
- MYH1 | c.963C>T p.I321= | Silent (SNP) | VAF 102/396 reads (26%) | called by muse, mutect2, varscan2
- MYH3 | c.4503G>A p.R1501= | Silent (SNP) | VAF 82/295 reads (28%) | catalogued as rs1417184471; called by muse, mutect2, varscan2
- MYO5B | c.2313C>T p.I771= | Silent (SNP) | VAF 76/362 reads (21%) | called by muse, mutect2, varscan2
- MYO7A | c.5427G>A p.L1809= | Silent (SNP) | VAF 219/320 reads (68%) | catalogued as rs1236366063; called by muse, mutect2, varscan2
- MYOCD | c.1695C>T p.F565= | Silent (SNP) | VAF 84/463 reads (18%) | catalogued as rs761036201, COSV58496475; called by muse, mutect2, varscan2
- NBEA | c.7494C>T p.I2498= | Silent (SNP) | VAF 59/342 reads (17%) | catalogued as rs745924046; called by muse, mutect2, varscan2
- NLGN4X | c.1020C>T p.F340= | Silent (SNP) | VAF 172/435 reads (40%) | catalogued as rs9699273; ClinVar: benign; called by muse, mutect2, varscan2
- NLRP14 | c.1434C>T p.F478= | Silent (SNP) | VAF 274/449 reads (61%) | catalogued as rs1565016988; called by muse, mutect2, varscan2
- NLRP5 | c.1809C>T p.I603= | Silent (SNP) | VAF 185/440 reads (42%) | catalogued as rs754634321, COSV66764135; called by muse, mutect2, varscan2
- NMUR2 | c.1179C>T p.L393= | Silent (SNP) | VAF 153/364 reads (42%) | called by muse, mutect2
- NPC1L1 | c.2619G>A p.Q873= | Silent (SNP) | VAF 207/601 reads (34%) | called by muse, mutect2, varscan2
- NUAK2 | c.1818C>T p.S606= | Silent (SNP) | VAF 214/509 reads (42%) | catalogued as COSV65682618; called by muse, mutect2, varscan2
- OCLN | c.390C>T p.G130= | Silent (SNP) | VAF 235/510 reads (46%) | called by muse, mutect2, varscan2
- ODC1 | c.567C>T p.I189= | Silent (SNP) | VAF 135/298 reads (45%) | catalogued as rs776935446, COSV52171876; called by muse, mutect2, varscan2
- OPRL1 | c.99C>T p.P33= | Silent (SNP) | VAF 313/731 reads (43%) | catalogued as rs980611931; called by muse, mutect2, varscan2
- OR10D3 | c.915G>A p.R305= | Silent (SNP) | VAF 117/207 reads (57%) | called by muse, mutect2, varscan2
- OR10P1 | c.522C>T p.I174= | Silent (SNP) | VAF 188/416 reads (45%) | catalogued as COSV59006921; called by muse, mutect2, varscan2
- OR2A7 | c.801G>A p.K267= | Silent (SNP) | VAF 172/1120 reads (15%) | called by muse, varscan2
- OR2T6 | c.186C>T p.L62= | Silent (SNP) | VAF 428/914 reads (47%) | catalogued as rs751517612, COSV63216245; called by muse, mutect2, varscan2
- OR5AK2 | c.627C>T p.F209= | Silent (SNP) | VAF 90/425 reads (21%) | called by muse, mutect2, varscan2
- OR8D1 | c.768C>T p.T256= | Silent (SNP) | VAF 220/335 reads (66%) | catalogued as rs1321225033; called by muse, mutect2, varscan2
- OR8G1 | c.315C>T p.L105= | Silent (SNP) | VAF 258/423 reads (61%) | catalogued as rs764095532, COSV58379860; called by muse, mutect2, varscan2
- OSMR | c.1149C>T p.I383= | Silent (SNP) | VAF 124/270 reads (46%) | catalogued as COSV57091741; called by muse, mutect2, varscan2
- OTOG | c.4692G>A p.K1564= | Silent (SNP) | VAF 325/532 reads (61%) | called by muse, mutect2, varscan2
- OTUD7A | c.1035C>T p.I345= (on ENST00000307050 / NM_001382637.1; = p.I338= on NM_130901.3) | Silent (SNP) | VAF 67/344 reads (19%) | called by muse, mutect2, varscan2
- P2RY14 | c.924G>A p.K308= | Silent (SNP) | VAF 74/336 reads (22%) | called by muse, mutect2, varscan2
- PCDHB11 | c.921G>A p.L307= | Silent (SNP) | VAF 128/302 reads (42%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.699G>A p.L233= | Silent (SNP) | VAF 162/391 reads (41%) | called by muse, mutect2, varscan2
- PDCL3 | c.63C>T p.P21= | Silent (SNP) | VAF 41/295 reads (14%) | called by muse, mutect2, varscan2
- PDE6C | c.1332G>A p.K444= | Silent (SNP) | VAF 97/190 reads (51%) | catalogued as rs200428306; called by muse, mutect2, varscan2
- PGAP4 | c.441G>A p.E147= | Silent (SNP) | VAF 185/378 reads (49%) | catalogued as rs947433426; called by muse, mutect2, varscan2
- PHF12 | c.1047C>T p.V349= | Silent (SNP) | VAF 163/465 reads (35%) | catalogued as rs775096182; called by muse, mutect2, varscan2
- PIK3C2G | c.1251G>A p.L417= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- PLBD1 | c.726T>A p.L242= | Silent (SNP) | VAF 57/245 reads (23%) | catalogued as COSV53692330; called by muse, mutect2, varscan2
- PLCH1 | c.2829G>A p.K943= (on ENST00000340059 / NM_001130960.2; = p.K935= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/405 reads (22%) | catalogued as rs1403095668, COSV58202974; called by muse, mutect2, varscan2
- PLG | c.1548C>T p.F516= | Silent (SNP) | VAF 76/301 reads (25%) | catalogued as COSV51984355; called by muse, mutect2, varscan2
- PMFBP1 | c.2319G>A p.Q773= (on ENST00000537465; = p.Q768= on NM_031293.3) | Silent (SNP) | VAF 73/263 reads (28%) | called by muse, mutect2, varscan2
- PNKP | c.1131G>A p.G377= | Silent (SNP) | VAF 97/417 reads (23%) | called by muse, mutect2, varscan2
- POM121L2 | c.2292C>T p.F764= | Silent (SNP) | VAF 200/637 reads (31%) | called by muse, mutect2, varscan2
- PPP1R16A | c.454C>T p.L152= | Silent (SNP) | VAF 141/401 reads (35%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.666C>T p.I222= | Silent (SNP) | VAF 100/508 reads (20%) | called by muse, mutect2, varscan2
- PRDM9 | c.708C>T p.N236= | Silent (SNP) | VAF 270/595 reads (45%) | catalogued as rs1416627416; called by muse, mutect2, varscan2
- PREX2 | c.2310A>G p.K770= | Silent (SNP) | VAF 138/483 reads (29%) | called by muse, mutect2, varscan2
- PREX2 | c.3711G>A p.R1237= | Silent (SNP) | VAF 75/223 reads (34%) | catalogued as COSV55748771; called by muse, mutect2, varscan2
- PRR35 | c.1680C>T p.V560= | Silent (SNP) | VAF 71/351 reads (20%) | called by muse, mutect2, varscan2
- PRUNE2 | c.1191C>T p.P397= | Silent (SNP) | VAF 183/326 reads (56%) | catalogued as rs1193662297, COSV65040795; called by muse, mutect2, varscan2
- PSD4 | c.1098G>A p.V366= | Silent (SNP) | VAF 61/337 reads (18%) | called by muse, mutect2, varscan2
- PTPRT | c.2250G>A p.V750= | Silent (SNP) | VAF 78/625 reads (12%) | called by muse, mutect2, varscan2
- RELN | c.108C>T p.F36= | Silent (SNP) | VAF 300/825 reads (36%) | called by muse, mutect2, varscan2
- RFPL4A | c.354C>T p.F118= | Silent (SNP) | VAF 94/796 reads (12%) | called by muse, mutect2, varscan2
- RHPN1 | c.1605C>T p.I535= | Silent (SNP) | VAF 143/411 reads (35%) | catalogued as rs761464642, COSV56644751; called by muse, mutect2, varscan2
- RIMBP2 | c.411C>T p.F137= | Silent (SNP) | VAF 149/367 reads (41%) | called by muse, mutect2, varscan2
- RPS18 | c.81C>T p.A27= | Silent (SNP) | VAF 142/490 reads (29%) | called by muse, varscan2
- SAG | c.633C>T p.V211= | Silent (SNP) | VAF 65/302 reads (22%) | catalogued as rs773755736; called by muse, mutect2, varscan2
- SCFD2 | c.420G>A p.L140= | Silent (SNP) | VAF 87/392 reads (22%) | called by muse, mutect2, varscan2
- SCN11A | c.4584C>T p.I1528= | Silent (SNP) | VAF 125/259 reads (48%) | catalogued as rs753282934, COSV100182423, COSV56566615; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN8A | c.2073C>T p.Y691= | Silent (SNP) | VAF 69/365 reads (19%) | catalogued as rs146982102; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SEC31B | c.3012C>T p.L1004= | Silent (SNP) | VAF 136/245 reads (56%) | called by muse, mutect2, varscan2
- SHROOM1 | c.36C>T p.S12= | Silent (SNP) | VAF 91/425 reads (21%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.663C>T p.I221= | Silent (SNP) | VAF 114/554 reads (21%) | called by muse, mutect2, varscan2
- SLC15A5 | c.1017G>A p.L339= | Silent (SNP) | VAF 75/285 reads (26%) | called by muse, mutect2, varscan2
- SLC36A2 | c.666G>A p.R222= | Silent (SNP) | VAF 69/344 reads (20%) | called by muse, mutect2, varscan2
- SLC46A3 | c.714C>T p.F238= | Silent (SNP) | VAF 172/290 reads (59%) | called by muse, mutect2, varscan2
- SLC9A1 | c.408C>T p.I136= | Silent (SNP) | VAF 127/462 reads (27%) | catalogued as rs759669008, COSV56057150; called by muse, mutect2, varscan2
- SLFN13 | c.948G>A p.V316= | Silent (SNP) | VAF 182/502 reads (36%) | catalogued as COSV53194785; called by muse, mutect2, varscan2
- SMPD4 | c.901C>T p.L301= | Silent (SNP) | VAF 46/290 reads (16%) | called by muse, mutect2, varscan2
- SNTG2 | c.1569C>A p.P523= | Silent (SNP) | VAF 84/404 reads (21%) | called by muse, mutect2, varscan2
- SPTA1 | c.4932C>T p.N1644= | Silent (SNP) | VAF 147/539 reads (27%) | catalogued as rs767312094; called by muse, mutect2, varscan2
- SPTBN1 | c.6897C>T p.I2299= | Silent (SNP) | VAF 53/291 reads (18%) | called by muse, mutect2, varscan2
- SSTR1 | c.1164C>T p.I388= | Silent (SNP) | VAF 66/246 reads (27%) | catalogued as COSV57457631; called by muse, mutect2, varscan2
- TCF4 | c.99G>A p.G33= | Silent (SNP) | VAF 81/381 reads (21%) | catalogued as rs767888662, COSV61904746; called by muse, mutect2, varscan2
- TDRD5 | c.1071G>A p.R357= | Silent (SNP) | VAF 197/451 reads (44%) | catalogued as rs1436071969, COSV99675178; called by muse, mutect2, varscan2
- TDRD7 | c.1767T>A p.P589= | Silent (SNP) | VAF 126/226 reads (56%) | catalogued as rs1277127110; called by muse, mutect2, varscan2
- TENM3 | c.7467C>T p.F2489= | Silent (SNP) | VAF 87/435 reads (20%) | catalogued as rs1348381770, COSV69317055; called by muse, mutect2, varscan2
- TERB1 | c.684C>T p.L228= | Silent (SNP) | VAF 73/292 reads (25%) | called by muse, mutect2, varscan2
- TEX33 | c.327G>T p.S109= (on ENST00000381821 / NM_001163857.2; = p.S24= on NM_178552.4) | Silent (SNP) | VAF 83/425 reads (20%) | called by muse, mutect2, varscan2
- THSD7B | c.309C>T p.L103= | Silent (SNP) | VAF 186/428 reads (43%) | catalogued as rs1261362001, COSV99747950, COSV99750059; called by muse, mutect2
- THSD7B | c.1239C>T p.V413= | Silent (SNP) | VAF 68/388 reads (18%) | called by muse, mutect2, varscan2
- THSD7B | c.3525T>C p.P1175= (on ENST00000272643; = p.P1173= on NM_001316349.2) | Silent (SNP) | VAF 148/345 reads (43%) | called by muse, mutect2, varscan2
- TMEM132D | c.975G>A p.K325= | Silent (SNP) | VAF 120/293 reads (41%) | called by muse, mutect2, varscan2
- TMEM150B | c.33C>T p.F11= | Silent (SNP) | VAF 129/301 reads (43%) | catalogued as COSV58592977; called by muse, mutect2, varscan2
- TMEM272 | c.321C>T p.I107= | Silent (SNP) | VAF 178/295 reads (60%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.1321C>T p.L441= | Silent (SNP) | VAF 48/274 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF25 | c.123G>A p.K41= | Silent (SNP) | VAF 81/394 reads (21%) | catalogued as COSV61069262; called by muse, mutect2, varscan2
- TNPO1 | c.2346A>G p.T782= | Silent (SNP) | VAF 74/337 reads (22%) | called by muse, mutect2, varscan2
- TPSD1 | c.126G>A p.Q42= | Silent (SNP) | VAF 72/382 reads (19%) | catalogued as rs771150292; called by mutect2, varscan2
- TRBV27 | c.273G>A p.R91= | Silent (SNP) | VAF 266/563 reads (47%) | called by muse, mutect2, varscan2
- TRIM50 | c.1236C>T p.H412= | Silent (SNP) | VAF 236/772 reads (31%) | called by muse, varscan2
- TRIM67 | c.468C>T p.S156= | Silent (SNP) | VAF 315/764 reads (41%) | called by muse, mutect2, varscan2
- TRMT44 | c.1239C>T p.F413= | Silent (SNP) | VAF 111/277 reads (40%) | catalogued as rs1193728427, COSV67664960; called by muse, mutect2, varscan2
- TRPS1 | c.2430C>T p.S810= (on ENST00000220888 / NM_001330599.2; = p.S823= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 175/426 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.24162G>A p.E8054= (on ENST00000591111; = p.E7127= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/270 reads (39%) | catalogued as rs766125478, COSV60299591; called by muse, mutect2, varscan2
- TTN | c.20130G>A p.G6710= (on ENST00000591111; = p.G5783= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/358 reads (18%) | catalogued as rs777605427, COSV59912298; called by muse, mutect2, varscan2
- UBTFL1 | c.537G>A p.K179= | Silent (SNP) | VAF 42/264 reads (16%) | called by muse, mutect2, varscan2
- UGT2A1 | c.72G>A p.L24= | Silent (SNP) | VAF 64/300 reads (21%) | catalogued as COSV54138765; called by muse, mutect2, varscan2
- ULK4 | c.2157C>T p.S719= | Silent (SNP) | VAF 44/259 reads (17%) | called by muse, mutect2, varscan2
- UMODL1 | c.3105C>T p.L1035= (on ENST00000408910 / NM_001004416.2; = p.L1163= on NM_173568.3) | Silent (SNP) | VAF 85/393 reads (22%) | catalogued as COSV101252422; called by muse, mutect2, varscan2
- UNC5C | c.192C>T p.F64= | Silent (SNP) | VAF 69/330 reads (21%) | catalogued as COSV71660989; called by muse, mutect2, varscan2
- VN1R2 | c.930G>A p.G310= | Silent (SNP) | VAF 139/374 reads (37%) | catalogued as COSV59038765; called by muse, mutect2, varscan2
- VSTM2A | c.354G>A p.R118= | Silent (SNP) | VAF 215/663 reads (32%) | catalogued as rs868057963; called by muse, mutect2, varscan2
- VWA5B2 | c.519C>T p.L173= | Silent (SNP) | VAF 80/421 reads (19%) | catalogued as rs746895747; called by muse, mutect2
- WDR12 | c.504C>T p.L168= | Silent (SNP) | VAF 117/297 reads (39%) | catalogued as rs1197397533; called by muse, mutect2, varscan2
- WFIKKN2 | c.1710G>A p.K570= | Silent (SNP) | VAF 80/255 reads (31%) | called by muse, mutect2, varscan2
- ZBTB7C | c.900C>T p.P300= | Silent (SNP) | VAF 181/427 reads (42%) | called by muse, mutect2, varscan2
- ZFHX3 | c.3537C>T p.S1179= | Silent (SNP) | VAF 59/202 reads (29%) | called by muse, mutect2, varscan2
- ZNF443 | c.756G>C p.P252= | Silent (SNP) | VAF 56/258 reads (22%) | catalogued as COSV56890733; called by muse, mutect2, varscan2
- ZNF564 | c.1500C>T p.T500= | Silent (SNP) | VAF 113/319 reads (35%) | catalogued as rs571292569; called by muse, mutect2, varscan2
- ZNRF4 | c.1194G>A p.L398= | Silent (SNP) | VAF 123/505 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN2 | c.1633C>T p.L545= | Silent (SNP) | VAF 281/654 reads (43%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.1413C>T p.C471= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as rs770557116, COSV54576631; called by muse, mutect2, varscan2
- ABCA7 | c.499-84A>G | Intron (SNP) | VAF 172/365 reads (47%) | called by muse, mutect2, varscan2
- ADGRB2 | c.3354-127C>T | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99926028; called by muse, mutect2, varscan2
- ATP10B | c.470+867G>A | Intron (SNP) | VAF 86/194 reads (44%) | called by muse, mutect2, varscan2
- C6orf223 | n.117-27G>A | Intron (SNP) | VAF 49/318 reads (15%) | called by muse, mutect2, varscan2
- CCDC150 | c.1866+671C>T | Intron (SNP) | VAF 80/365 reads (22%) | catalogued as rs776966080, COSV55879627; called by muse, mutect2, varscan2
- DEPDC5 | c.2120+134T>A | Intron (SNP) | VAF 143/223 reads (64%) | called by muse, mutect2, varscan2
- DLG1 | c.2005-776C>T | Intron (SNP) | VAF 54/220 reads (25%) | catalogued as rs776452461, COSV58391332; called by muse, mutect2, varscan2
- EPB41L3 | c.2350-609C>T | Intron (SNP) | VAF 94/278 reads (34%) | catalogued as rs113004100; called by muse, mutect2, varscan2
- GOLGA3 | c.-153G>A | 5'UTR (SNP) | VAF 105/262 reads (40%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+682G>A | Intron (SNP) | VAF 280/590 reads (47%) | catalogued as rs778950295; called by muse, mutect2, varscan2
- ITGA6 | c.3232-2256C>T | Intron (SNP) | VAF 47/254 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22754C>T | Intron (SNP) | VAF 52/242 reads (21%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+975A>G | Intron (SNP) | VAF 139/214 reads (65%) | called by muse, mutect2, varscan2
- MRPL11 | c.473+234C>T | Intron (SNP) | VAF 174/278 reads (63%) | called by muse, mutect2, varscan2
- NR4A2 | c.-117T>C | 5'UTR (SNP) | VAF 88/235 reads (37%) | called by muse, mutect2, varscan2
- PKD1L2 | n.3001C>G | RNA (SNP) | VAF 68/279 reads (24%) | catalogued as rs929531799; called by mutect2, varscan2
- SH2D3C | c.516-5485G>A | Intron (SNP) | VAF 186/339 reads (55%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.707-11T>A | Intron (SNP) | VAF 54/344 reads (16%) | called by muse, mutect2, varscan2
- STON2 | c.2784+96C>T | Intron (SNP) | VAF 105/222 reads (47%) | catalogued as rs764419645, COSV50844753; called by muse, mutect2, varscan2
- SUCO | chr1:172532480 G>A | 5'Flank (SNP) | VAF 94/344 reads (27%) | catalogued as COSV99743494; called by muse, mutect2, varscan2
- TRIM11 | c.859+101C>T | Intron (SNP) | VAF 85/622 reads (14%) | called by muse, mutect2, varscan2
- TTC39C | c.985-905A>T | Intron (SNP) | VAF 49/271 reads (18%) | called by muse, mutect2, varscan2
- TTC39C | c.985-904G>A | Intron (SNP) | VAF 47/267 reads (18%) | called by muse, mutect2, varscan2
